Somatic mutation profile of tumor specimen C3L-06096-02 (aliquot CPT0360900009) from CPTAC case C3L-06096, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 63.7 years (23,277 days).
Specimen C3L-06096-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d7f35ba-fa73-41c4-999e-b2c979275f10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06096-31 (Blood Derived Normal), aliquot CPT0360990002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21f08063-697c-4160-8734-af82e0f70244

The open-access MAF lists 731 somatic variants for this specimen: 480 protein-altering or splice-affecting, 224 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 427, Silent 224, Nonsense Mutation 31, Intron 14, Splice Region 10, Splice Site 6, Frame Shift Del 5, 5'Flank 4, RNA 3, 3'UTR 3, 3'Flank 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 192/422 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 191/420 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GRIN2A | c.2191G>A p.D731N | Missense Mutation (SNP) | VAF 79/251 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs796052549, CM138250, COSV58045061; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MFN2 | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 121/432 reads (28%) | catalogued as rs866604005, COSV52420774; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACACA | c.2786C>T p.P929L | Missense Mutation (SNP) | VAF 73/372 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs61738839; called by muse, mutect2, varscan2
- ADAM22 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 164/638 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs370014529, COSV55969068; called by muse, mutect2, varscan2
- ADAMTS20 | c.3941G>T p.G1314V | Missense Mutation (SNP) | VAF 78/242 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101166342; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.61A>T p.M21L | Missense Mutation (SNP) | VAF 104/358 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs747320072; called by muse, mutect2, varscan2
- AFDN | c.3733C>T p.P1245S | Missense Mutation (SNP) | VAF 116/350 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.046); catalogued as COSV60059185; called by muse, mutect2, varscan2
- AGPAT3 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 115/349 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV104394866; called by muse, mutect2, varscan2
- ALOX5AP | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as rs146973182, COSV66857950; called by muse, mutect2, varscan2
- ARFGEF3 | c.5803G>A p.D1935N | Missense Mutation (SNP) | VAF 147/437 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs771537463, COSV52475520; called by muse, mutect2, varscan2
- ARRDC4 | c.892C>T p.H298Y | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV51418744; called by muse, mutect2, varscan2
- ASXL2 | c.4082C>T p.S1361L | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55465061; called by muse, mutect2, varscan2
- ASXL3 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1458407413; called by muse, mutect2, varscan2
- ATP2C2 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 48/287 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs1483259768, COSV52295152; called by muse, mutect2, varscan2
- AXDND1 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 105/366 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs868380930, COSV62648005; called by muse, mutect2, varscan2
- B9D2 | c.75G>A p.W25* | Nonsense Mutation (SNP) | VAF 86/304 reads (28%) | catalogued as COSV99699208; called by muse, mutect2
- BATF2 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 157/402 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV57249701; called by muse, mutect2, varscan2
- BCAT2 | c.47_48dup p.V17Lfs*26 | Frame Shift Ins (INS) | VAF 32/247 reads (13%) | catalogued as rs763388954; called by mutect2, varscan2
- BICDL2 | c.498G>A p.Q166= | Splice Region (SNP) | VAF 69/317 reads (22%) | catalogued as rs1190836413; called by muse, mutect2, varscan2
- C5AR1 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 102/388 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs146163744, COSV100754070; called by muse, mutect2, varscan2
- CACNA1F | c.2128G>A p.G710S | Missense Mutation (SNP) | VAF 80/144 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs376156915; called by muse, mutect2, varscan2
- CACNA1H | c.4610C>T p.S1537F | Missense Mutation (SNP) | VAF 47/318 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867334518; called by muse, mutect2, varscan2
- CALR3 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as rs543953490, COSV54169548; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAMSAP3 | c.2267C>T p.S756F | Missense Mutation (SNP) | VAF 74/498 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs764492054; called by muse, mutect2, varscan2
- CCDC102B | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 53/214 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV60134843; called by muse, mutect2, varscan2
- CD5L | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 139/487 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as rs183099720, COSV63823202; called by muse, mutect2, varscan2
- CDCP2 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 129/458 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61283535; called by muse, mutect2
- CDH18 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 118/348 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776963132, COSV56899350; called by muse, mutect2, varscan2
- CDH6 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 90/243 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV54065814; called by muse, mutect2, varscan2
- CEP128 | c.2834A>T p.D945V | Missense Mutation (SNP) | VAF 70/400 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV55369688; called by muse, mutect2, varscan2
- CHD6 | c.2996C>T p.S999F | Missense Mutation (SNP) | VAF 76/278 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100498793; called by muse, mutect2, varscan2
- CHRDL1 | c.426+1G>A p.X142_splice (on ENST00000372045; = p.X148_splice on NM_145234.4) | Splice Site (SNP) | VAF 103/175 reads (59%) | catalogued as COSV54327034; called by muse, mutect2, varscan2
- CLCN5 | c.2148C>T p.N716= | Splice Region (SNP) | VAF 89/160 reads (56%) | catalogued as rs782105613, COSV56582442; called by muse, mutect2, varscan2
- CLEC5A | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 132/543 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69396699; called by muse, mutect2, varscan2
- CLSTN2 | c.1978C>T p.P660S | Missense Mutation (SNP) | VAF 43/275 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as rs763454601; called by muse, mutect2, varscan2
- CLSTN2 | c.2212G>A p.G738S | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757537210, COSV71721196; called by muse, mutect2, varscan2
- COG7 | c.1913C>T p.P638L | Missense Mutation (SNP) | VAF 93/287 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100207578, COSV100207914; called by muse, mutect2, varscan2
- COL11A1 | c.3028G>A p.D1010N | Missense Mutation (SNP) | VAF 71/235 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1267946269, COSV62190573; called by muse, mutect2, varscan2
- CP | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 57/235 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as rs1286440771, COSV52829767; called by muse, mutect2, varscan2
- CPAMD8 | c.3374C>T p.S1125F (on ENST00000651564; = p.S1078F on NM_015692.5) | Missense Mutation (SNP) | VAF 70/397 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV71597415; called by muse, mutect2, varscan2
- CYB5D2 | c.252C>T p.G84= | Splice Region (SNP) | VAF 66/240 reads (28%) | catalogued as rs143079411; called by muse, mutect2, varscan2
- CYFIP2 | c.3097C>T p.L1033F (on ENST00000616178 / NM_001291722.2; = p.L1008F on NM_014376.4) | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV59048316; called by muse, mutect2, varscan2
- CYP3A43 | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 220/519 reads (42%) | SIFT tolerated (0.83); PolyPhen benign (0.021); catalogued as COSV55937858; called by muse, mutect2, varscan2
- DACH1 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 69/202 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs998407261; called by muse, mutect2, varscan2
- DCC | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 114/460 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); catalogued as rs1167613349; called by muse, mutect2, varscan2
- DCD | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 62/281 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV53201171; called by muse, mutect2, varscan2
- DHX40 | c.663C>A p.F221L | Missense Mutation (SNP) | VAF 48/278 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV52066656; called by muse, mutect2, varscan2
- DISP2 | c.3812C>T p.P1271L | Missense Mutation (SNP) | VAF 149/414 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV99140767; called by muse, mutect2, varscan2
- DNAH11 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 81/318 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs758299855; called by muse, mutect2, varscan2
- DNAH5 | c.4714C>T p.L1572F | Missense Mutation (SNP) | VAF 85/244 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs769020798; called by muse, mutect2, varscan2
- DNAH5 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 53/192 reads (28%) | catalogued as rs771463510, CM091929; called by muse, mutect2, varscan2
- DNAH8 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as rs138901149; called by muse, mutect2, varscan2
- DNMBP | c.1775C>T p.S592F | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs746750816; called by muse, mutect2, varscan2
- DNPEP | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 80/321 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1182494773, COSV56110187; called by muse, mutect2, varscan2
- DST | c.17045C>T p.P5682L (on ENST00000361203 / NM_001374722.1; = p.P3379L on NM_015548.5) | Missense Mutation (SNP) | VAF 57/397 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs762167722; called by muse, mutect2, varscan2
- DTX3L | c.1073C>T p.S358F | Missense Mutation (SNP) | VAF 81/289 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs1380043811; called by muse, mutect2, varscan2
- DUXA | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 71/341 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV73729537; called by muse, mutect2, varscan2
- ELAC2 | c.2245C>T p.H749Y | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762471494; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPPK1 | c.5391G>A p.W1797* | Nonsense Mutation (SNP) | VAF 132/430 reads (31%) | catalogued as rs1563881121, COSV101599973; called by muse, mutect2, varscan2
- EYS | c.2351C>T p.S784F | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV65527410; called by muse, mutect2, varscan2
- F11 | c.1514G>A p.G505E | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.475); catalogued as COSV53002408; called by muse, mutect2, varscan2
- F5 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 135/385 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs752636369, COSV63123123; called by muse, mutect2, varscan2
- FAM160A1 | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 110/381 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as rs1295457560; called by muse, mutect2, varscan2
- FAM184A | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 123/335 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58855666; called by muse, mutect2, varscan2
- FBXL18 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 168/541 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV66665171; called by muse, varscan2
- FBXO10 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 132/348 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV52836826; called by muse, mutect2, varscan2
- FEV | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 132/431 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.477); catalogued as rs1028971914; called by muse, mutect2, varscan2
- FEZ1 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 77/237 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99631053; called by muse, mutect2, varscan2
- FRAS1 | c.7085G>A p.R2362Q | Missense Mutation (SNP) | VAF 81/362 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as rs865839705, COSV53631054; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FURIN | c.1718C>T p.T573I | Missense Mutation (SNP) | VAF 87/319 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776984234; called by muse, mutect2, varscan2
- FYB2 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 88/322 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.037); catalogued as rs751789084; called by muse, mutect2, varscan2
- GALNT6 | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 54/221 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV62542024; called by muse, mutect2, varscan2
- GALNT6 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 100/423 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV62542442; called by muse, mutect2, varscan2
- GJD2 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 97/329 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0.021); catalogued as COSV99290790; called by muse, mutect2, varscan2
- GLI3 | c.3190C>T p.P1064S | Missense Mutation (SNP) | VAF 131/488 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs199876743; called by muse, mutect2, varscan2
- GOLGA8S | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763755056; called by muse, mutect2, varscan2
- GPATCH8 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 56/312 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as COSV59194383; called by muse, mutect2, varscan2
- GPR158 | c.2872C>T p.P958S | Missense Mutation (SNP) | VAF 67/367 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0.015); catalogued as rs1564501907, COSV66268011, COSV66283827; called by muse, mutect2, varscan2
- GPR162 | c.1495G>A p.G499S (on ENST00000311268 / NM_019858.2; = p.G215S on NM_014449.2) | Missense Mutation (SNP) | VAF 119/482 reads (25%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.109); catalogued as rs782440772; called by muse, mutect2, varscan2
- GRK3 | c.1978C>T p.R660C | Missense Mutation (SNP) | VAF 85/400 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.842); catalogued as rs1005491210, COSV60793935; called by muse, mutect2, varscan2
- GRM1 | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 66/449 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV51164397; called by muse, mutect2, varscan2
- GRXCR1 | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 78/298 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs755984447; called by muse, mutect2, varscan2
- GUCY1A2 | c.2071C>T p.P691S | Missense Mutation (SNP) | VAF 97/268 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs376266445; called by muse, mutect2, varscan2
- HEPACAM2 | c.517G>A p.E173K (on ENST00000394468 / NM_001039372.4; = p.E161K on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/694 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.257); catalogued as COSV59060462; called by muse, mutect2, varscan2
- HS3ST5 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 108/330 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100451339; called by muse, mutect2, varscan2
- HTT | c.2212C>T p.P738S | Missense Mutation (SNP) | VAF 93/297 reads (31%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV61869869; called by muse, mutect2, varscan2
- IDO1 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV53714778; called by muse, mutect2, varscan2
- IFRD2 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 52/291 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100269911; called by muse, mutect2, varscan2
- IL1R1 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV52107077; called by muse, mutect2, varscan2
- IL1RL2 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 68/209 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.709); catalogued as rs866058726, COSV51812942, COSV51816541; called by muse, mutect2, varscan2
- IMPG1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs1234278469, COSV100885867; called by muse, mutect2, varscan2
- INTS1 | c.3034C>T p.P1012S | Missense Mutation (SNP) | VAF 118/451 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs763380995; called by muse, mutect2, varscan2
- INTS1 | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 102/341 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as rs1002330500; called by muse, mutect2, varscan2
- IRF8 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 40/279 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.719); catalogued as COSV51897213; called by muse, mutect2, varscan2
- ITGA2B | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 85/350 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as rs761397037; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2366C>T p.T789I | Missense Mutation (SNP) | VAF 53/399 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV100311620; called by muse, mutect2, varscan2
- KERA | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 87/392 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57131174; called by muse, mutect2, varscan2
- KIAA0586 | c.964C>T p.P322S (on ENST00000619416 / NM_001244190.2; = p.P337S on NM_014749.5) | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV99707243; called by muse, mutect2, varscan2
- KLHL34 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 119/239 reads (50%) | catalogued as rs1290641108; called by muse, mutect2, varscan2
- KMT2B | c.7299G>A p.G2433= | Splice Region (SNP) | VAF 66/264 reads (25%) | catalogued as COSV99718759; called by muse, mutect2, varscan2
- KNDC1 | c.5019G>A p.R1673= | Splice Region (SNP) | VAF 32/197 reads (16%) | catalogued as rs931449468; called by muse, mutect2, varscan2
- KRT16 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 115/626 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs755292687; called by muse, mutect2, varscan2
- KRT6B | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 133/814 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52884893; called by muse, mutect2, varscan2
- LECT2 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773806450; called by muse, mutect2, varscan2
- LGSN | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV101040612; called by muse, mutect2, varscan2
- LILRA1 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 140/533 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs996685403; called by muse, mutect2, varscan2
- LILRB1 | c.31C>T p.H11Y | Missense Mutation (SNP) | VAF 125/576 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.208); catalogued as rs771389914; called by muse, mutect2, varscan2
- LIPF | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.499); catalogued as COSV53286270; called by muse, mutect2, varscan2
- LPA | c.2980C>T p.P994S | Missense Mutation (SNP) | VAF 40/259 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV60300473; called by muse, mutect2, varscan2
- LRIT2 | c.1616G>A p.G539E | Missense Mutation (SNP) | VAF 48/239 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60560321; called by muse, mutect2, varscan2
- LRIT2 | c.1615G>A p.G539R | Missense Mutation (SNP) | VAF 48/242 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs750188057; called by muse, mutect2, varscan2
- LRP2 | c.13847C>T p.S4616L | Missense Mutation (SNP) | VAF 69/350 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs140802648; called by muse, mutect2, varscan2
- LRRC15 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 72/342 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.732); catalogued as rs267599743, COSV61649800; called by muse, mutect2, varscan2
- LRRC37A3 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 92/1134 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as rs768806565, COSV59761184; called by muse, mutect2
- LRRN1 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 75/351 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100075962; called by muse, mutect2, varscan2
- LYPD8 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 120/467 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs1553283078; called by muse, mutect2, varscan2
- LZTS3 | c.1747G>A p.E583K (on ENST00000329152; = p.E537K on NM_001282533.2) | Missense Mutation (SNP) | VAF 131/548 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as rs938318193; called by muse, mutect2, varscan2
- MAGEL2 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 203/718 reads (28%) | SIFT deleterious, low confidence (0); catalogued as rs183812337, COSV58568463; called by muse, mutect2, varscan2
- MAMDC2 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 103/277 reads (37%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.46); catalogued as COSV101015872; called by muse, mutect2, varscan2
- MAP7 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV63418665; called by muse, mutect2, varscan2
- MAPT | c.1571C>T p.T524I (on ENST00000262410 / NM_001377265.1; = p.T449I on NM_016835.4) | Missense Mutation (SNP) | VAF 101/377 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.317); catalogued as rs1401903524; called by muse, mutect2, varscan2
- MATK | c.676G>A p.A226T (on ENST00000310132 / NM_139355.3; = p.A227T on NM_002378.4) | Missense Mutation (SNP) | VAF 75/257 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as COSV100036341; called by muse, mutect2, varscan2
- MBTD1 | c.1801G>A p.D601N | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.135); catalogued as rs1020705113; called by muse, mutect2, varscan2
- MCM9 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 100/339 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1199370804, COSV60323483; called by muse, mutect2, varscan2
- MCU | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV64068823; called by muse, mutect2, varscan2
- MDGA2 | c.958C>T p.P320S (on ENST00000399232 / NM_001113498.2; = p.P22S on NM_182830.4) | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.923); catalogued as COSV62081244; called by muse, mutect2, varscan2
- MED13L | c.2596C>T p.P866S | Missense Mutation (SNP) | VAF 63/285 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867033906, COSV56116816; called by muse, mutect2, varscan2
- MET | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 141/738 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.114); catalogued as COSV59270915; called by muse, mutect2, varscan2
- MORC1 | c.773G>A p.R258K | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51715146; called by muse, mutect2, varscan2
- MROH2A | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.861); catalogued as rs1222452858; called by muse, mutect2, varscan2
- MS4A4A | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100557862, COSV59700812; called by muse, mutect2, varscan2
- MUC12 | c.10979G>A p.R3660Q (on ENST00000379442; = p.R3517Q on NM_001164462.1) | Missense Mutation (SNP) | VAF 78/1888 reads (4%) | SIFT tolerated (0.59); catalogued as rs4729636, COSV65194648; called by muse, mutect2
- MUC16 | c.37277C>T p.P12426L | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.201); catalogued as rs1314478101, COSV67470763; called by muse, mutect2, varscan2
- MUC16 | c.20116C>T p.H6706Y | Missense Mutation (SNP) | VAF 43/295 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.041); catalogued as COSV67441860; called by muse, mutect2, varscan2
- MUC16 | c.19823C>T p.S6608L | Missense Mutation (SNP) | VAF 56/294 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs746016038, COSV67445814, COSV67466930; called by muse, mutect2, varscan2
- MUC16 | c.16828C>T p.R5610W | Missense Mutation (SNP) | VAF 58/356 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.718); catalogued as rs753471783, COSV101199553, COSV67466155; called by muse, mutect2, varscan2
- MUC16 | c.9086C>T p.S3029F | Missense Mutation (SNP) | VAF 79/266 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs761426902, COSV67481410; called by muse, mutect2, varscan2
- MUC22 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 236/620 reads (38%) | SIFT tolerated (0.24); catalogued as rs1191427207; called by muse, mutect2, varscan2
- MUC3A | c.8315C>T p.T2772I | Missense Mutation (SNP) | VAF 98/1064 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.537); catalogued as rs1359216268; called by muse, mutect2
- MUC4 | c.13063C>T p.R4355C (on ENST00000463781 / NM_018406.7; = p.R119C on NM_004532.6) | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs770422854, COSV57777523; called by muse, mutect2, varscan2
- MYH4 | c.3670G>T p.E1224* | Nonsense Mutation (SNP) | VAF 47/294 reads (16%) | catalogued as COSV55122787; called by muse, mutect2, varscan2
- MYH4 | c.3568G>A p.E1190K | Missense Mutation (SNP) | VAF 50/368 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs766733986, COSV55118667; called by muse, mutect2, varscan2
- MYO18B | c.1147G>A p.G383R | Missense Mutation (SNP) | VAF 117/478 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.025); catalogued as rs1404721984; called by muse, mutect2, varscan2
- MYO18B | c.5776G>A p.E1926K | Missense Mutation (SNP) | VAF 75/345 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as rs754080627; called by muse, mutect2, varscan2
- MYO18B | c.7117G>A p.D2373N | Missense Mutation (SNP) | VAF 116/442 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as COSV59129734; called by muse, mutect2, varscan2
- NCAM2 | c.1993C>G p.Q665E | Missense Mutation (SNP) | VAF 94/361 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs1223111527; called by muse, mutect2, varscan2
- NCAPH | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 65/250 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV53638483; called by muse, mutect2, varscan2
- NCKAP1L | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53206265; called by muse, mutect2, varscan2
- NCKAP5 | c.4922C>T p.S1641F | Missense Mutation (SNP) | VAF 109/356 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100491360; called by muse, mutect2, varscan2
- NDST4 | c.2371C>T p.R791C | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.139); catalogued as rs1190760162, COSV52107697; called by muse, mutect2, varscan2
- NEXMIF | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 139/269 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747436946, COSV50021850; called by muse, mutect2, varscan2
- NPAS4 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 92/263 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100215335; called by muse, mutect2, varscan2
- OASL | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 89/372 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376037465; called by muse, mutect2, varscan2
- OR10A5 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV55053159; called by muse, mutect2, varscan2
- OR11H12 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 68/396 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as rs1433316990; called by muse, mutect2, varscan2
- OR13C4 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 132/355 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV52926182; called by muse, mutect2, varscan2
- OR8S1 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 115/428 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1402505526, COSV100043666, COSV59600095; called by muse, mutect2, varscan2
- OR9A4 | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 108/650 reads (17%) | catalogued as rs782594459, COSV71885022; called by muse, mutect2, varscan2
- PACRGL | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 101/370 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs1204330957, COSV54842713; called by muse, mutect2, varscan2
- PAK5 | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 101/410 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV62032087; called by muse, mutect2, varscan2
- PAPPA2 | c.3709C>T p.P1237S | Missense Mutation (SNP) | VAF 112/407 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV62811287; called by muse, mutect2, varscan2
- PCCB | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs141956198, CM1110008; called by muse, mutect2
- PCDH15 | c.4532G>A p.R1511K | Missense Mutation (SNP) | VAF 55/273 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.089); catalogued as rs267602527; called by muse, mutect2, varscan2
- PCDHA3 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 161/451 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.941); catalogued as rs782236184; called by muse, mutect2, varscan2
- PCDHB16 | c.2134del p.R712Gfs*28 | Frame Shift Del (DEL) | VAF 117/439 reads (27%) | catalogued as COSV53357508; called by mutect2, pindel, varscan2
- PCDHB4 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 111/318 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV52021873; called by muse, mutect2, varscan2
- PCDHB4 | c.2311C>T p.P771S | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.057); catalogued as COSV52027758; called by muse, mutect2, varscan2
- PCLO | c.7709C>T p.P2570L | Missense Mutation (SNP) | VAF 248/599 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV61615127; called by muse, mutect2, varscan2
- PCLO | c.2858G>A p.G953E | Missense Mutation (SNP) | VAF 151/539 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as rs1317053689, COSV61636706; called by muse, mutect2, varscan2
- PCSK5 | c.1846C>T p.R616C | Missense Mutation (SNP) | VAF 117/333 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs779558515, COSV65089141; called by muse, mutect2, varscan2
- PDK4 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 248/553 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV50012441; called by muse, mutect2, varscan2
- PEG3 | c.1652G>T p.S551I | Missense Mutation (SNP) | VAF 85/389 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55642707; called by muse, varscan2
- PEG3 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 96/374 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV55641782; called by muse, varscan2
- PER3 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 120/418 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV62706776; called by muse, mutect2, varscan2
- PIWIL3 | c.2167C>T p.R723W | Missense Mutation (SNP) | VAF 85/391 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs752254479, COSV59995327; called by muse, mutect2, varscan2
- PKHD1L1 | c.2287C>T p.Q763* | Nonsense Mutation (SNP) | VAF 37/219 reads (17%) | catalogued as COSV65745070; called by muse, mutect2, varscan2
- PLCH1 | c.1612G>A p.E538K (on ENST00000340059 / NM_001130960.2; = p.E550K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV58197532; called by muse, mutect2, varscan2
- PLEKHA7 | c.2017C>T p.R673W | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs760552278; called by muse, mutect2, varscan2
- PLXNA4 | c.2050G>A p.D684N | Missense Mutation (SNP) | VAF 78/476 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as rs1432455576, COSV58154550; called by muse, mutect2, varscan2
- PNLIP | c.1167C>T p.F389= | Splice Region (SNP) | VAF 21/122 reads (17%) | catalogued as rs1209306578, COSV100981760, COSV65041904; called by muse, mutect2, varscan2
- PPP1R16A | c.271C>T p.L91F | Missense Mutation (SNP) | VAF 63/351 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1197773173; called by muse, mutect2, varscan2
- PRDM14 | c.1574C>T p.S525F | Missense Mutation (SNP) | VAF 103/353 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV52574594; called by muse, mutect2, varscan2
- PRH2 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 120/768 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.071); catalogued as rs1437293288; called by muse, varscan2
- PRLR | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 75/215 reads (35%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.906); catalogued as rs868089715; called by muse, mutect2, varscan2
- PRR23C | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 124/445 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.21); catalogued as rs776258606, COSV68827525; called by muse, mutect2, varscan2
- RAI2 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 106/183 reads (58%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs989599739, COSV58966671; called by muse, mutect2, varscan2
- RALGAPA2 | c.4594C>T p.P1532S | Missense Mutation (SNP) | VAF 117/462 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1247270337; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1595C>T p.S532F | Missense Mutation (SNP) | VAF 86/350 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs367545939; called by muse, mutect2, varscan2
- RGPD3 | c.4102G>A p.D1368N | Missense Mutation (SNP) | VAF 119/470 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs761955204, COSV58737868; called by muse, mutect2, varscan2
- RGPD4 | c.3778G>A p.D1260N | Missense Mutation (SNP) | VAF 138/451 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.948); catalogued as rs776911077; called by muse, mutect2, varscan2
- RIMS1 | c.2668C>T p.H890Y | Missense Mutation (SNP) | VAF 104/350 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs868676989; called by muse, mutect2, varscan2
- RP1 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 67/428 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.072); catalogued as COSV55121175; called by muse, mutect2, varscan2
- RTTN | c.578G>A p.S193N | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV55351495; called by muse, mutect2, varscan2
- SCN1A | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 91/349 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57685284; called by muse, mutect2, varscan2
- SCN2A | c.5890G>A p.D1964N | Missense Mutation (SNP) | VAF 35/287 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.59); catalogued as rs1384231143; called by muse, mutect2, varscan2
- SCN3A | c.4120G>A p.D1374N | Missense Mutation (SNP) | VAF 57/405 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV51805516, COSV99328857; called by muse, mutect2, varscan2
- SCN5A | c.4299G>A p.G1433= (on ENST00000333535 / NM_198056.3; = p.G1432= on NM_000335.5) | Splice Region (SNP) | VAF 32/194 reads (16%) | catalogued as rs794728935, CS100772; called by muse, mutect2, varscan2
- SERPINA10 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 80/470 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370084509, COSV56229286; called by muse, mutect2, varscan2
- SERPINA7 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 131/265 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.097); catalogued as COSV59665225; called by muse, mutect2, varscan2
- SIGLEC14 | c.1013G>A p.R338K | Missense Mutation (SNP) | VAF 46/375 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV55778832, COSV55785230; called by muse, mutect2, varscan2
- SLC16A3 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 67/402 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746409901; called by muse, mutect2, varscan2
- SLC16A9 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 55/260 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143724578, COSV68098313; called by muse, mutect2, varscan2
- SLC35G3 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 118/605 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV52012774; called by muse, mutect2, varscan2
- SLC9A2 | c.1029G>A p.M343I | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV52137823; called by muse, mutect2, varscan2
- SLIT2 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 87/296 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV56587419; called by muse, mutect2, varscan2
- SLIT2 | c.2875C>T p.H959Y | Missense Mutation (SNP) | VAF 100/398 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV56564619; called by muse, mutect2
- SLITRK3 | c.1939C>T p.P647S | Missense Mutation (SNP) | VAF 56/333 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV53851108; called by muse, mutect2, varscan2
- SPTA1 | c.5677G>A p.E1893K | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.062); catalogued as COSV63750730; called by muse, mutect2, varscan2
- SSX7 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.077); catalogued as rs1352184981, COSV99994052; called by muse, mutect2, varscan2
- SYCP1 | c.636G>A p.M212I | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV101051257; called by muse, mutect2, varscan2
- SYCP2L | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 104/258 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs777634406; called by muse, mutect2, varscan2
- SYT1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 78/327 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs138582600, COSV54034805; called by muse, mutect2, varscan2
- TARS3 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 46/313 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs1376692079, COSV100255071; called by muse, mutect2, varscan2
- TAS2R16 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 156/693 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.331); catalogued as rs1254452071; called by muse, mutect2, varscan2
- TCF4 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 65/272 reads (24%) | SIFT deleterious, low confidence (0); catalogued as rs767361180; called by muse, mutect2, varscan2
- TCHHL1 | c.2324G>A p.W775* | Nonsense Mutation (SNP) | VAF 110/429 reads (26%) | catalogued as rs1241521526; called by muse, mutect2, varscan2
- TEX35 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 74/310 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs547829770; called by muse, mutect2, varscan2
- THSD4 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 68/428 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.249); catalogued as rs1294847470, COSV55961307; called by muse, mutect2, varscan2
- TLL1 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 104/459 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99288750; called by muse, mutect2, varscan2
- TLR4 | c.2390G>A p.W797* (on ENST00000355622 / NM_138554.5; = p.W757* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 88/271 reads (32%) | catalogued as COSV62923505; called by muse, mutect2, varscan2
- TMPRSS15 | c.1234C>T p.L412F | Missense Mutation (SNP) | VAF 47/347 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53035743; called by muse, mutect2, varscan2
- TNFRSF11A | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 118/548 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.197); catalogued as rs1463920572, COSV99500115; called by muse, mutect2, varscan2
- TNR | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 119/446 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.332); catalogued as rs531733667, COSV54868765; called by muse, mutect2, varscan2
- TNRC6A | c.2363C>T p.P788L | Missense Mutation (SNP) | VAF 101/397 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs1169974791, COSV100170311; called by muse, mutect2, varscan2
- TNRC6B | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 91/352 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs928049973; called by muse, mutect2, varscan2
- TOGARAM2 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 101/331 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65423935; called by muse, mutect2, varscan2
- TRAV26-1 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1433701912; called by muse, mutect2, varscan2
- TRIM50 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 326/687 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1554543453; called by muse, mutect2, varscan2
- TRIM51 | c.1327C>T p.L443F | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs747995913; called by muse, mutect2, varscan2
- TRPM2 | c.3178G>A p.D1060N | Missense Mutation (SNP) | VAF 97/295 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55976612; called by muse, mutect2, varscan2
- TRPM5 | c.1918G>A p.D640N | Missense Mutation (SNP) | VAF 82/265 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs746962321; called by muse, mutect2, varscan2
- TRRAP | c.5867C>T p.T1956I (on ENST00000359863 / NM_001244580.1; = p.T1938I on NM_003496.3) | Missense Mutation (SNP) | VAF 101/612 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs782485850; called by muse, mutect2, varscan2
- TTN | c.74079G>A p.W24693* (on ENST00000591111; = p.W17269* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 114/352 reads (32%) | catalogued as COSV60195965; called by muse, mutect2, varscan2
- TTN | c.28859G>A p.G9620E (on ENST00000591111; = p.G8693E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/312 reads (15%) | PolyPhen probably damaging (1); catalogued as rs867130730, COSV60171505; called by muse, mutect2, varscan2
- UGT1A1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 75/445 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0.014); catalogued as COSV100529745; called by muse, mutect2, varscan2
- UGT2B11 | c.1567G>A p.G523R | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs1329086651, COSV71423115; called by muse, mutect2, varscan2
- UMOD | c.1160G>A p.G387D | Missense Mutation (SNP) | VAF 70/401 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs767354465; called by muse, mutect2, varscan2
- VWDE | c.2207G>A p.G736E | Missense Mutation (SNP) | VAF 161/545 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs760102281; called by muse, mutect2, varscan2
- WDFY4 | c.7126G>A p.E2376K | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs1302649425; called by muse, mutect2, varscan2
- WDFY4 | c.8605G>A p.G2869S | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.294); catalogued as rs1468796938, COSV55425703; called by muse, mutect2, varscan2
- WDR72 | c.1810C>T p.L604F | Missense Mutation (SNP) | VAF 54/308 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64744129; called by muse, mutect2, varscan2
- WSCD2 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV54577201, COSV54585482; called by muse, mutect2, varscan2
- WWP1 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 51/266 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.615); catalogued as COSV99615568; called by muse, mutect2, varscan2
- YLPM1 | c.1607C>T p.P536L | Missense Mutation (SNP) | VAF 148/532 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV53108321; called by muse, mutect2, varscan2
- ZFHX4 | c.5669C>T p.S1890F | Missense Mutation (SNP) | VAF 69/314 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51468908, COSV51480339, COSV99269107; called by muse, mutect2, varscan2
- ZFHX4 | c.8588A>G p.K2863R | Missense Mutation (SNP) | VAF 94/343 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.171); catalogued as rs371910142; called by muse, mutect2, varscan2
- ZHX2 | c.1514C>T p.S505F | Missense Mutation (SNP) | VAF 102/318 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV58710881; called by muse, mutect2, varscan2
- ZMAT4 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 78/320 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52691559; called by muse, mutect2, varscan2
- ZNF730 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 27/276 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); catalogued as COSV74168473; called by muse, mutect2, varscan2
- ZNF780B | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 116/526 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55464458; called by muse, mutect2, varscan2
- ZRANB3 | c.2611C>T p.L871F | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs749289959; called by muse, mutect2, varscan2
- ZSWIM5 | c.1090A>G p.M364V | Missense Mutation (SNP) | VAF 71/274 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs1196653025; called by muse, mutect2, varscan2
- AADACL2 | c.1105G>A p.G369R | Missense Mutation (SNP) | VAF 48/251 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC090517.4 | c.2068G>C p.G690R | Missense Mutation (SNP) | VAF 55/228 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ACAP2 | c.1321C>T p.H441Y | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACAP3 | c.915G>A p.K305= | Splice Region (SNP) | VAF 98/442 reads (22%) | called by muse, mutect2, varscan2
- ACD | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 78/381 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- ACOXL | c.197G>A p.R66K | Missense Mutation (SNP) | VAF 92/328 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACRBP | c.1289G>A p.G430E | Missense Mutation (SNP) | VAF 103/387 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- ACTL9 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 113/479 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- ADAD1 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 72/283 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- ADAM22 | c.1940A>C p.D647A | Missense Mutation (SNP) | VAF 86/481 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ADAMTS18 | c.3445C>T p.H1149Y | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- ADAMTS7 | c.4730C>T p.P1577L | Missense Mutation (SNP) | VAF 76/307 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADD2 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 107/362 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRG4 | c.378G>A p.W126* | Nonsense Mutation (SNP) | VAF 145/274 reads (53%) | called by muse, mutect2, varscan2
- ADORA1 | c.898C>T p.L300F | Missense Mutation (SNP) | VAF 105/417 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ADPRHL1 | c.5305C>T p.Q1769* | Nonsense Mutation (SNP) | VAF 94/768 reads (12%) | called by muse, varscan2
- ALB | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 72/309 reads (23%) | called by muse, mutect2, varscan2
- ALMS1 | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 82/272 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ANK3 | c.8111C>T p.P2704L | Missense Mutation (SNP) | VAF 52/303 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD18A | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- ANKRD28 | c.2476C>T p.P826S | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ANKRD31 | c.5251G>A p.D1751N | Missense Mutation (SNP) | VAF 102/274 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, varscan2
- ANXA9 | c.566G>A p.S189N | Missense Mutation (SNP) | VAF 107/342 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- AOC3 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 91/385 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- APH1B | c.552A>C p.K184N | Missense Mutation (SNP) | VAF 64/322 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- APRT | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 154/460 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGEF5 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 25/384 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASTN1 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 119/436 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ATG9B | c.2402C>T p.S801F | Missense Mutation (SNP) | VAF 118/505 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATP7A | c.1844C>T p.P615L | Missense Mutation (SNP) | VAF 100/186 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP8A1 | c.3171C>A p.F1057L | Missense Mutation (SNP) | VAF 90/349 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATR | c.2857C>T p.P953S | Missense Mutation (SNP) | VAF 73/404 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.021); called by muse, mutect2
- AWAT1 | c.494A>T p.Y165F | Missense Mutation (SNP) | VAF 141/257 reads (55%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- BICDL2 | c.498+1G>A p.X166_splice | Splice Site (SNP) | VAF 68/314 reads (22%) | called by muse, mutect2, varscan2
- C10orf71 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- C1orf21 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 66/295 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CACNA1A | c.1459C>T p.Q487* | Nonsense Mutation (SNP) | VAF 47/322 reads (15%) | called by muse, mutect2, varscan2
- CACNA1C | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 89/354 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CACNA1C | c.2531G>A p.G844E | Missense Mutation (SNP) | VAF 47/263 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CADPS | c.2799G>A p.M933I | Missense Mutation (SNP) | VAF 52/267 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CCDC174 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD96 | c.1198C>T p.P400S (on ENST00000283285 / NM_198196.3; = p.P384S on NM_005816.5) | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- CDH9 | c.1036A>G p.R346G | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- CFAP54 | c.6316G>A p.D2106N | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CHEK1 | c.1336G>A p.G446S | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRNA7 | c.55G>T p.V19L | Missense Mutation (SNP) | VAF 105/382 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLIC4 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 100/353 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- CNST | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 114/420 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CNTN5 | c.2476G>A p.V826M | Missense Mutation (SNP) | VAF 101/260 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRACR2A | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 103/364 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRB1 | c.2659G>A p.G887R | Missense Mutation (SNP) | VAF 95/322 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRISP1 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 106/279 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- CRPPA | c.847C>T p.Q283* (on ENST00000407010 / NM_001368197.1; = p.Q233* on NM_001101417.4) | Nonsense Mutation (SNP) | VAF 72/255 reads (28%) | called by muse, mutect2, varscan2
- CSMD3 | c.4622G>A p.G1541E (on ENST00000297405 / NM_001363185.1; = p.G1437E on NM_052900.3) | Missense Mutation (SNP) | VAF 63/358 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CSMD3 | c.3292G>A p.D1098N (on ENST00000297405 / NM_001363185.1; = p.D994N on NM_052900.3) | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- DACT3 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 82/359 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DHRSX | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 152/413 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHX34 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 112/382 reads (29%) | called by muse, mutect2, varscan2
- DLGAP2 | c.1305del p.S435Rfs*34 | Frame Shift Del (DEL) | VAF 130/486 reads (27%) | called by mutect2, pindel, varscan2
- DMRTB1 | c.95G>A p.W32* | Nonsense Mutation (SNP) | VAF 122/426 reads (29%) | called by muse, mutect2, varscan2
- DNAH1 | c.1571C>T p.T524I | Missense Mutation (SNP) | VAF 51/270 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH17 | c.8511+1G>A p.X2837_splice | Splice Site (SNP) | VAF 38/166 reads (23%) | called by muse, mutect2, varscan2
- DNER | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 83/283 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOCK8 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 116/300 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DPYS | c.1133C>T p.T378I | Missense Mutation (SNP) | VAF 90/291 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNAP | c.418G>A p.G140R (on ENST00000321600; = p.G114R on NM_173629.3) | Missense Mutation (SNP) | VAF 55/373 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2444A>G p.N815S | Missense Mutation (SNP) | VAF 53/333 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- EGFLAM | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ERMARD | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 116/272 reads (43%) | called by muse, mutect2, varscan2
- EYS | c.4454G>A p.R1485K | Missense Mutation (SNP) | VAF 78/261 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- F13B | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 79/344 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM13C | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FCRL1 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 69/329 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FLNC | c.6949G>A p.V2317M | Missense Mutation (SNP) | VAF 174/829 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FMO3 | c.627G>A p.Q209= | Splice Region (SNP) | VAF 66/288 reads (23%) | called by muse, mutect2, varscan2
- FOXK1 | c.1789C>T p.P597S | Missense Mutation (SNP) | VAF 176/552 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GAL3ST1 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 93/407 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- GDF10 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 83/323 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- GEM | c.11A>T p.N4I | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- GJA5 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 110/450 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GOLGA6C | c.1909G>A p.G637R | Missense Mutation (SNP) | VAF 16/499 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- GPRC6A | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 101/285 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HERC6 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 59/308 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HRG | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 78/383 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- HSF1 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 155/423 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- HYDIN | c.13393G>A p.E4465K | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- IDO2 | c.722G>A p.W241* (on ENST00000389060; = p.W254* on NM_194294.2) | Nonsense Mutation (SNP) | VAF 40/238 reads (17%) | called by muse, mutect2
- IFNA17 | c.491G>T p.W164L | Missense Mutation (SNP) | VAF 89/286 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV3-66 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 65/430 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- IGKV2D-24 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 44/324 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- IKBKB | c.1475T>C p.I492T | Missense Mutation (SNP) | VAF 111/364 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ITGA3 | c.2699C>T p.T900I | Missense Mutation (SNP) | VAF 67/252 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITGB4 | c.2806C>T p.Q936* | Nonsense Mutation (SNP) | VAF 84/282 reads (30%) | called by muse, mutect2, varscan2
- JCAD | c.2920C>T p.P974S | Missense Mutation (SNP) | VAF 68/291 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- KALRN | c.1235C>T p.T412I | Missense Mutation (SNP) | VAF 43/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KARS1 | c.1414T>G p.L472V | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KAT6A | c.5849C>T p.P1950L | Missense Mutation (SNP) | VAF 102/397 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNA5 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 131/449 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- KCNA5 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 131/450 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KCNH7 | c.2833C>T p.Q945* | Nonsense Mutation (SNP) | VAF 69/379 reads (18%) | called by muse, mutect2, varscan2
- KCNU1 | c.3325C>T p.Q1109* | Nonsense Mutation (SNP) | VAF 86/308 reads (28%) | called by muse, mutect2, varscan2
- KIAA1671 | c.2458C>T p.P820S | Missense Mutation (SNP) | VAF 110/441 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- KIF11 | c.1934T>C p.V645A | Missense Mutation (SNP) | VAF 37/249 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF21B | c.4858C>T p.P1620S (on ENST00000422435 / NM_001252100.2; = p.P1607S on NM_017596.4) | Missense Mutation (SNP) | VAF 122/438 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KPNA4 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- KRT3 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- KRT37 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 153/544 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2
- LAMA5 | c.3642_3645delinsTTTT p.P1215F | Missense Mutation (ONP) | VAF 29/302 reads (10%) | called by pindel, varscan2*
- LCORL | c.991C>T p.H331Y | Missense Mutation (SNP) | VAF 84/382 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LCT | c.4598G>A p.W1533* | Nonsense Mutation (SNP) | VAF 55/294 reads (19%) | called by muse, mutect2, varscan2
- LFNG | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 178/613 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, varscan2
- LGALS3BP | c.1384C>T p.Q462* | Nonsense Mutation (SNP) | VAF 102/397 reads (26%) | called by muse, mutect2, varscan2
- LINC02218 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 98/250 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LRP2 | c.2793G>A p.W931* | Nonsense Mutation (SNP) | VAF 34/374 reads (9%) | called by muse, mutect2
- LRP5 | c.1601G>C p.G534A | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- LTB4R2 | c.854C>T p.P285L (on ENST00000528054; = p.P254L on NM_019839.5) | Missense Mutation (SNP) | VAF 131/578 reads (23%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- LTF | c.900C>A p.D300E | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MALRD1 | c.4928G>A p.G1643E | Missense Mutation (SNP) | VAF 60/278 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- MAP3K6 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 132/454 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MAPT | c.1864C>T p.R622C (on ENST00000262410 / NM_001377265.1; = p.R230C on NM_005910.5) | Missense Mutation (SNP) | VAF 100/498 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAS1 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 103/324 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MBOAT4 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 105/374 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MED10 | c.126T>A p.N42K | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MMP25 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 110/378 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MT4 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MUC16 | c.38231T>C p.V12744A | Missense Mutation (SNP) | VAF 77/317 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- MYH8 | c.4393G>A p.E1465K | Missense Mutation (SNP) | VAF 71/256 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- MYT1L | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYZAP | c.1291G>A p.D431N (on ENST00000267853 / NM_001018100.5; = p.D403N on NM_152451.7) | Missense Mutation (SNP) | VAF 69/294 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- NADSYN1 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 117/258 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NANOG | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 73/336 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- NEB | c.7705G>A p.E2569K | Missense Mutation (SNP) | VAF 59/385 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NECTIN4 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 114/426 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NEIL3 | c.1106C>G p.T369S | Missense Mutation (SNP) | VAF 66/323 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- NEIL3 | c.1157del p.G386Efs*7 | Frame Shift Del (DEL) | VAF 66/344 reads (19%) | called by pindel, varscan2
- NELL1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 82/224 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- NPAP1 | c.2204C>T p.P735L | Missense Mutation (SNP) | VAF 118/398 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NPIPA8 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- NPY2R | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 117/434 reads (27%) | called by muse, mutect2, varscan2
- NRK | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 116/234 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- NUP153 | c.3401C>T p.S1134F | Missense Mutation (SNP) | VAF 55/397 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- NUP54 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 67/256 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NUP98 | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 93/258 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NYNRIN | c.4048C>T p.P1350S | Missense Mutation (SNP) | VAF 86/466 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR2C3 | c.866T>C p.L289P | Missense Mutation (SNP) | VAF 118/470 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.425); called by muse, mutect2
- OR2G6 | c.260A>C p.K87T | Missense Mutation (SNP) | VAF 126/485 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- OR51B6 | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 116/332 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- OR51I2 | c.476T>C p.L159P | Missense Mutation (SNP) | VAF 86/237 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PALB2 | c.2753C>T p.P918L | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHAC1 | c.1943C>T p.S648F | Missense Mutation (SNP) | VAF 111/317 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PDE4B | c.1660C>T p.Q554* | Nonsense Mutation (SNP) | VAF 59/231 reads (26%) | called by muse, mutect2, varscan2
- PDYN | c.529G>A p.G177S | Missense Mutation (SNP) | VAF 117/455 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PEMT | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 53/337 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- PER3 | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 85/308 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- PFKL | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 66/371 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PHGDH | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 109/370 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- PLXNB1 | c.2641C>T p.P881S | Missense Mutation (SNP) | VAF 51/342 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POLN | c.2458C>T p.L820F | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- POM121C | c.2636C>T p.S879F (on ENST00000607367; = p.S637F on NM_001099415.3) | Missense Mutation (SNP) | VAF 233/939 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PPIA | c.52_67del p.G18Sfs*17 | Frame Shift Del (DEL) | VAF 124/505 reads (25%) | called by mutect2, pindel, varscan2
- PRMT6 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 109/468 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- PTK7 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 128/308 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- PTPRS | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 73/212 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PWWP3B | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 143/268 reads (53%) | called by muse, mutect2, varscan2
- PYGO1 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 114/376 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- RASSF3 | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 123/432 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RBAK | c.1453C>T p.H485Y | Missense Mutation (SNP) | VAF 158/494 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RD3L | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 123/400 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- REELD1 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 92/320 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- REG1B | c.290A>T p.N97I | Missense Mutation (SNP) | VAF 47/287 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- RP1L1 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 68/426 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- RPRD2 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 91/401 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- RPS6KB2 | c.1058A>C p.E353A | Missense Mutation (SNP) | VAF 96/252 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- RSC1A1 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 137/475 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- RTL3 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 134/277 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- RTTN | c.578+1G>A p.X193_splice | Splice Site (SNP) | VAF 46/180 reads (26%) | called by muse, mutect2, varscan2
- RYR3 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 78/294 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SAMD9L | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 178/649 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SCML4 | c.76C>T p.H26Y | Missense Mutation (SNP) | VAF 129/328 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- SCNN1B | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 143/464 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SERPINA4 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 91/274 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- SERPINB10 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 85/346 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- SFRP4 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 121/498 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- SGMS2 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 108/378 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SHTN1 | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 101/368 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC28A2 | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 87/303 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- SLC4A1 | c.2593C>T p.L865F | Missense Mutation (SNP) | VAF 97/351 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- SLC4A5 | c.2815G>A p.G939R | Missense Mutation (SNP) | VAF 48/278 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A7 | c.1089C>T p.G363= | Splice Region (SNP) | VAF 34/127 reads (27%) | called by muse, mutect2, varscan2
- SLC6A7 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SNCAIP | c.2243C>A p.P748Q | Missense Mutation (SNP) | VAF 82/233 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SON | c.6002C>T p.S2001L | Missense Mutation (SNP) | VAF 92/369 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPNS3 | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 71/372 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); called by muse, varscan2
- SPOCK2 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 53/261 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPPL2C | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 145/530 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- SPTAN1 | c.1227A>T p.E409D | Missense Mutation (SNP) | VAF 73/160 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- SSBP4 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 140/405 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SSX1 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 88/165 reads (53%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- STARD9 | c.12194C>T p.S4065F | Missense Mutation (SNP) | VAF 73/386 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- STRIP1 | c.752A>G p.E251G | Missense Mutation (SNP) | VAF 70/285 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SYNDIG1L | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- TAAR8 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 106/350 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TACC2 | c.5110G>A p.E1704K | Missense Mutation (SNP) | VAF 55/382 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TACC2 | c.7033C>T p.P2345S (on ENST00000334433; = p.P423S on NM_006997.4) | Missense Mutation (SNP) | VAF 66/381 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAS2R16 | c.360G>A p.W120* | Nonsense Mutation (SNP) | VAF 405/766 reads (53%) | called by muse, mutect2, varscan2
- TCHHL1 | c.2325G>A p.W775* | Nonsense Mutation (SNP) | VAF 107/425 reads (25%) | called by muse, mutect2, varscan2
- TENM1 | c.2651+1G>A p.X884_splice | Splice Site (SNP) | VAF 69/124 reads (56%) | called by muse, mutect2, varscan2
- THRB | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 79/325 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- TOPORS | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 101/301 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TPCN2 | c.2237del p.P746Rfs*51 | Frame Shift Del (DEL) | VAF 96/288 reads (33%) | called by mutect2, pindel*, varscan2
- TRANK1 | c.4634A>T p.N1545I | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRPM1 | c.3952C>T p.P1318S | Missense Mutation (SNP) | VAF 62/458 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- TSC22D4 | c.26G>T p.S9I | Missense Mutation (SNP) | VAF 120/524 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- TTN | c.35504T>C p.V11835A (on ENST00000591111; = p.V10908A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/228 reads (32%) | PolyPhen benign (0.075); called by muse, mutect2, varscan2
- TTN | c.29647+1G>A p.X9883_splice (on ENST00000591111; = p.X8956_splice on NM_133378.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 32/231 reads (14%) | called by muse, mutect2, varscan2
- UGP2 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- UGT2B11 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 84/390 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UMOD | c.1159G>A p.G387S | Missense Mutation (SNP) | VAF 70/407 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- VTI1B | c.488T>C p.I163T | Missense Mutation (SNP) | VAF 100/353 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZFHX3 | c.5599C>T p.L1867F | Missense Mutation (SNP) | VAF 56/329 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ZNF316 | c.1891C>T p.P631S | Missense Mutation (SNP) | VAF 154/468 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- ZNF444 | c.70C>A p.R24S | Missense Mutation (SNP) | VAF 144/479 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZNF578 | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 101/372 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZNF711 | c.2195C>T p.P732L | Missense Mutation (SNP) | VAF 106/209 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF721 | c.2210G>A p.G737E (on ENST00000338977; = p.G749E on NM_133474.4) | Missense Mutation (SNP) | VAF 95/380 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZNF768 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 82/446 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABI3 | c.750C>T p.V250= | Silent (SNP) | VAF 77/405 reads (19%) | catalogued as rs375202610; called by muse, mutect2, varscan2
- AC090517.4 | c.1968C>T p.N656= | Silent (SNP) | VAF 26/218 reads (12%) | called by muse, mutect2, varscan2
- ACTL8 | c.153G>A p.V51= | Silent (SNP) | VAF 124/431 reads (29%) | called by muse, mutect2, varscan2
- ADAD2 | c.300C>T p.P100= | Silent (SNP) | VAF 87/479 reads (18%) | catalogued as rs538269915; called by muse, mutect2, varscan2
- ADAMTS10 | c.924G>A p.G308= | Silent (SNP) | VAF 31/298 reads (10%) | catalogued as rs1555740437, COSV54359412; called by muse, mutect2, varscan2
- ADAMTS20 | c.1503C>T p.P501= | Silent (SNP) | VAF 83/284 reads (29%) | catalogued as rs1024410550, COSV101239666; called by muse, mutect2, varscan2
- AJM1 | c.2295C>T p.F765= | Silent (SNP) | VAF 139/357 reads (39%) | called by muse, mutect2, varscan2
- AKAP8L | c.1093T>C p.L365= | Silent (SNP) | VAF 34/248 reads (14%) | catalogued as rs1007745068; called by muse, mutect2, varscan2
- ALPK1 | c.2620C>T p.L874= | Silent (SNP) | VAF 93/395 reads (24%) | catalogued as rs1372985236; called by muse, mutect2, varscan2
- AMBRA1 | c.1761C>T p.T587= (on ENST00000458649 / NM_001367468.1; = p.T497= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 115/279 reads (41%) | catalogued as COSV100095051; called by muse, mutect2, varscan2
- AMELX | c.414G>A p.Q138= | Silent (SNP) | VAF 209/380 reads (55%) | called by muse, mutect2, varscan2
- AMPD1 | c.2307C>T p.L769= | Silent (SNP) | VAF 71/286 reads (25%) | called by muse, mutect2, varscan2
- ANK3 | c.1911C>T p.I637= | Silent (SNP) | VAF 25/164 reads (15%) | catalogued as rs539885495, COSV55078786; called by muse, mutect2, varscan2
- ANKRD30A | c.3774G>A p.R1258= (on ENST00000611781; = p.R1202= on NM_052997.2) | Silent (SNP) | VAF 37/224 reads (17%) | catalogued as COSV64606841; called by muse, mutect2, varscan2
- ANKRD30A | c.4104G>A p.E1368= (on ENST00000611781; = p.E1312= on NM_052997.2) | Silent (SNP) | VAF 21/123 reads (17%) | catalogued as rs1333328634; called by muse, mutect2, varscan2
- ANO10 | c.615G>A p.G205= | Silent (SNP) | VAF 35/181 reads (19%) | called by muse, mutect2, varscan2
- ANO2 | c.2325G>A p.R775= (on ENST00000356134 / NM_001278597.3; = p.R779= on NM_001278596.3) | Silent (SNP) | VAF 102/426 reads (24%) | catalogued as rs1449867978, COSV59006516; called by muse, mutect2, varscan2
- ANXA10 | c.538C>T p.L180= | Silent (SNP) | VAF 80/323 reads (25%) | catalogued as COSV100829022; called by muse, mutect2, varscan2
- AOC3 | c.1905C>T p.T635= | Silent (SNP) | VAF 49/259 reads (19%) | catalogued as COSV53828317; called by muse, mutect2, varscan2
- ARHGAP18 | c.654C>T p.I218= | Silent (SNP) | VAF 78/250 reads (31%) | called by muse, mutect2, varscan2
- ARHGEF2 | c.2040C>T p.P680= (on ENST00000361247 / NM_001162383.2; = p.P652= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 126/418 reads (30%) | called by muse, mutect2, varscan2
- ASXL2 | c.3303C>T p.S1101= | Silent (SNP) | VAF 56/369 reads (15%) | called by muse, mutect2, varscan2
- ATL2 | c.1221T>C p.P407= | Silent (SNP) | VAF 42/261 reads (16%) | called by muse, mutect2, varscan2
- ATP1B1 | c.249C>T p.I83= | Silent (SNP) | VAF 96/311 reads (31%) | called by muse, mutect2, varscan2
- AXIN2 | c.2019C>T p.T673= | Silent (SNP) | VAF 109/526 reads (21%) | catalogued as rs1450619354; called by muse, mutect2, varscan2
- BCL6 | c.576A>T p.P192= | Silent (SNP) | VAF 82/409 reads (20%) | called by muse, mutect2, varscan2
- BCOR | c.759C>T p.V253= | Silent (SNP) | VAF 177/346 reads (51%) | catalogued as rs373674220; called by muse, mutect2, varscan2
- C16orf96 | c.84C>A p.L28= | Silent (SNP) | VAF 79/416 reads (19%) | called by muse, mutect2, varscan2
- C1orf21 | c.258C>T p.P86= | Silent (SNP) | VAF 66/296 reads (22%) | called by muse, mutect2, varscan2
- C1orf210 | c.138C>T p.L46= | Silent (SNP) | VAF 126/456 reads (28%) | catalogued as rs778390108; called by muse, mutect2, varscan2
- C5 | c.481T>C p.L161= | Silent (SNP) | VAF 60/143 reads (42%) | called by muse, mutect2, varscan2
- C6 | c.18C>T p.V6= | Silent (SNP) | VAF 72/197 reads (37%) | catalogued as COSV54710135; called by muse, mutect2, varscan2
- C6orf132 | c.753C>T p.P251= | Silent (SNP) | VAF 82/452 reads (18%) | called by muse, mutect2, varscan2
- CACNA1A | c.1830C>T p.S610= | Silent (SNP) | VAF 36/283 reads (13%) | catalogued as COSV100801052; called by muse, mutect2, varscan2
- CAMSAP3 | c.2268C>T p.S756= | Silent (SNP) | VAF 75/499 reads (15%) | called by muse, mutect2, varscan2
- CASR | c.2430C>T p.A810= (on ENST00000490131; = p.A887= on NM_000388.4) | Silent (SNP) | VAF 135/405 reads (33%) | called by muse, mutect2, varscan2
- CCDC141 | c.2805G>A p.R935= | Silent (SNP) | VAF 37/167 reads (22%) | called by muse, mutect2, varscan2
- CCDC141 | c.2589T>A p.V863= | Silent (SNP) | VAF 54/200 reads (27%) | called by muse, mutect2, varscan2
- CCDC39 | c.133T>C p.L45= | Silent (SNP) | VAF 40/218 reads (18%) | called by muse, mutect2, varscan2
- CD163L1 | c.819G>A p.G273= | Silent (SNP) | VAF 61/279 reads (22%) | called by muse, mutect2, varscan2
- CDH20 | c.1506C>T p.V502= | Silent (SNP) | VAF 58/297 reads (20%) | catalogued as COSV99404682; called by muse, mutect2, varscan2
- CDH4 | c.1521C>T p.F507= | Silent (SNP) | VAF 174/635 reads (27%) | catalogued as rs1209835351, COSV64668665; called by muse, mutect2, varscan2
- CEACAM20 | c.879C>T p.P293= | Silent (SNP) | VAF 102/460 reads (22%) | catalogued as COSV57603624; called by muse, mutect2, varscan2
- CFH | c.2718G>A p.R906= | Silent (SNP) | VAF 84/303 reads (28%) | catalogued as rs1244083287; called by muse, mutect2, varscan2
- CLCN1 | c.1239C>T p.F413= | Silent (SNP) | VAF 187/438 reads (43%) | catalogued as rs752532395; called by muse, mutect2, varscan2
- CLCN5 | c.702G>A p.K234= | Silent (SNP) | VAF 99/195 reads (51%) | called by muse, mutect2, varscan2
- CMTM8 | c.451C>T p.L151= | Silent (SNP) | VAF 38/175 reads (22%) | called by muse, mutect2, varscan2
- COL4A5 | c.1221G>A p.Q407= | Silent (SNP) | VAF 130/251 reads (52%) | called by muse, mutect2, varscan2
- COL5A3 | c.2520G>A p.E840= | Silent (SNP) | VAF 46/303 reads (15%) | called by muse, mutect2, varscan2
- CWH43 | c.1383C>T p.F461= | Silent (SNP) | VAF 69/273 reads (25%) | catalogued as COSV56939016; called by muse, mutect2, varscan2
- CYP11B1 | c.219G>A p.Q73= | Silent (SNP) | VAF 35/289 reads (12%) | called by muse, mutect2, varscan2
- CYP2C8 | c.615C>T p.F205= | Silent (SNP) | VAF 40/209 reads (19%) | catalogued as rs138050874; called by muse, mutect2, varscan2
- CYP2C9 | c.1299G>A p.R433= | Silent (SNP) | VAF 38/185 reads (21%) | catalogued as rs761946333; called by muse, mutect2, varscan2
- CYP4A22 | c.168C>T p.S56= | Silent (SNP) | VAF 112/416 reads (27%) | called by muse, mutect2, varscan2
- CYP4B1 | c.210G>A p.V70= | Silent (SNP) | VAF 70/346 reads (20%) | called by muse, mutect2, varscan2
- CYP4F3 | c.1500G>A p.R500= | Silent (SNP) | VAF 117/402 reads (29%) | catalogued as COSV55407134; called by muse, mutect2, varscan2
- CYRIA | c.534C>T p.V178= | Silent (SNP) | VAF 35/210 reads (17%) | called by muse, mutect2, varscan2
- D2HGDH | c.1242C>T p.I414= | Silent (SNP) | VAF 105/344 reads (31%) | catalogued as rs758849873; ClinVar: likely benign; called by muse, mutect2, varscan2
- DBX2 | c.420C>T p.F140= | Silent (SNP) | VAF 88/337 reads (26%) | catalogued as COSV60337557; called by muse, mutect2, varscan2
- DCAF4L2 | c.129C>T p.C43= | Silent (SNP) | VAF 103/302 reads (34%) | catalogued as COSV60479471; called by muse, mutect2, varscan2
- DCD | c.93G>A p.G31= | Silent (SNP) | VAF 71/304 reads (23%) | called by muse, mutect2, varscan2
- DCST1 | c.927G>A p.V309= | Silent (SNP) | VAF 110/434 reads (25%) | catalogued as rs763862619; called by muse, mutect2, varscan2
- DHX35 | c.1335C>T p.F445= | Silent (SNP) | VAF 49/220 reads (22%) | called by muse, mutect2, varscan2
- DLGAP2 | c.2757G>A p.Q919= | Silent (SNP) | VAF 113/301 reads (38%) | catalogued as COSV70103615; called by muse, mutect2, varscan2
- DNAH12 | c.78C>T p.L26= | Silent (SNP) | VAF 47/322 reads (15%) | catalogued as rs1004581242; called by muse, mutect2, varscan2
- DNAH5 | c.10107C>T p.F3369= | Silent (SNP) | VAF 72/177 reads (41%) | catalogued as COSV54224486, COSV54236601; called by muse, mutect2, varscan2
- DNAH5 | c.6861G>A p.R2287= | Silent (SNP) | VAF 74/224 reads (33%) | called by muse, mutect2, varscan2
- DNAH5 | c.4713C>T p.L1571= | Silent (SNP) | VAF 84/248 reads (34%) | called by muse, mutect2, varscan2
- DUOX2 | c.2880C>T p.I960= | Silent (SNP) | VAF 38/268 reads (14%) | called by muse, mutect2, varscan2
- EGFR | c.681C>T p.S227= | Silent (SNP) | VAF 141/494 reads (29%) | catalogued as rs1313321537; called by muse, mutect2, varscan2
- ENAM | c.876C>T p.L292= | Silent (SNP) | VAF 128/474 reads (27%) | called by muse, mutect2, varscan2
- F10 | c.1296C>T p.F432= | Silent (SNP) | VAF 119/345 reads (34%) | catalogued as rs139031355, COSV65021884; called by muse, mutect2, varscan2
- FAM110C | c.522C>T p.S174= | Silent (SNP) | VAF 149/531 reads (28%) | catalogued as rs1340420514; called by muse, mutect2, varscan2
- FAM83H | c.408C>T p.I136= | Silent (SNP) | VAF 96/531 reads (18%) | called by muse, mutect2, varscan2
- FIGNL2 | c.891C>T p.P297= | Silent (SNP) | VAF 125/517 reads (24%) | called by muse, mutect2, varscan2
- FREM3 | c.3765C>T p.F1255= | Silent (SNP) | VAF 116/392 reads (30%) | catalogued as rs1212479130; called by muse, mutect2, varscan2
- FSTL5 | c.915C>T p.S305= | Silent (SNP) | VAF 47/220 reads (21%) | called by muse, mutect2, varscan2
- GATA6 | c.1749C>T p.S583= | Silent (SNP) | VAF 87/322 reads (27%) | catalogued as rs142079702; called by muse, mutect2, varscan2
- GNAS | c.1836C>T p.L612= | Silent (SNP) | VAF 128/388 reads (33%) | catalogued as COSV58333505; called by muse, mutect2, varscan2
- GOT2 | c.507C>T p.F169= | Silent (SNP) | VAF 85/346 reads (25%) | catalogued as rs1475661043; called by muse, mutect2, varscan2
- GPR157 | c.873C>T p.F291= | Silent (SNP) | VAF 98/431 reads (23%) | called by muse, mutect2, varscan2
- GRAMD1C | c.435C>T p.I145= | Silent (SNP) | VAF 45/188 reads (24%) | called by muse, mutect2, varscan2
- GREB1 | c.5394C>T p.A1798= | Silent (SNP) | VAF 63/418 reads (15%) | catalogued as rs1245928004; called by muse, mutect2, varscan2
- GRPR | c.150C>T p.I50= | Silent (SNP) | VAF 133/268 reads (50%) | called by muse, mutect2, varscan2
- HBE1 | c.165C>T p.I55= | Silent (SNP) | VAF 88/234 reads (38%) | called by muse, mutect2, varscan2
- HRH3 | c.462G>A p.R154= | Silent (SNP) | VAF 106/404 reads (26%) | catalogued as COSV58047626; called by muse, mutect2, varscan2
- HS3ST2 | c.792C>T p.F264= | Silent (SNP) | VAF 100/393 reads (25%) | catalogued as COSV54458855; called by muse, mutect2, varscan2
- HTR5A | c.1008G>A p.L336= | Silent (SNP) | VAF 134/644 reads (21%) | called by muse, mutect2, varscan2
- HYDIN | c.2544C>T p.S848= | Silent (SNP) | VAF 19/153 reads (12%) | catalogued as COSV58571336; called by muse, mutect2, varscan2
- IBTK | c.3003T>C p.I1001= | Silent (SNP) | VAF 84/286 reads (29%) | called by muse, mutect2, varscan2
- IGHV1-18 | c.189G>A p.G63= | Silent (SNP) | VAF 75/283 reads (27%) | catalogued as rs377099600; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.108C>T p.S36= | Silent (SNP) | VAF 133/402 reads (33%) | catalogued as rs763424964; called by muse, mutect2, varscan2
- IGKV1-9 | c.96C>T p.F32= | Silent (SNP) | VAF 107/327 reads (33%) | catalogued as rs752555494; called by muse, mutect2, varscan2
- IGKV6D-21 | c.327G>A p.Q109= | Silent (SNP) | VAF 42/227 reads (19%) | called by muse, mutect2, varscan2
- INTS1 | c.3033C>T p.P1011= | Silent (SNP) | VAF 117/451 reads (26%) | catalogued as rs977447303, COSV67179750; called by muse, mutect2, varscan2
- INTS13 | c.1269G>A p.R423= | Silent (SNP) | VAF 52/218 reads (24%) | catalogued as rs751113804; called by muse, mutect2, varscan2
- ITGA1 | c.1020C>T p.F340= | Silent (SNP) | VAF 100/291 reads (34%) | catalogued as rs1163452814; called by muse, mutect2, varscan2
- IVL | c.1011G>A p.E337= | Silent (SNP) | VAF 138/569 reads (24%) | catalogued as rs1014365775; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2367C>T p.T789= | Silent (SNP) | VAF 53/399 reads (13%) | catalogued as rs375427577; called by muse, mutect2, varscan2
- KCNMB2 | c.513C>T p.H171= | Silent (SNP) | VAF 54/296 reads (18%) | catalogued as rs758356323; called by muse, mutect2, varscan2
- KCNN3 | c.2205C>T p.S735= (on ENST00000618040 / NM_001204087.1; = p.S720= on NM_002249.6) | Silent (SNP) | VAF 97/376 reads (26%) | called by muse, mutect2, varscan2
- KMT2A | c.10365G>A p.V3455= | Silent (SNP) | VAF 136/324 reads (42%) | called by muse, mutect2, varscan2
- KMT2B | c.1368C>T p.S456= | Silent (SNP) | VAF 135/474 reads (28%) | catalogued as rs768693126; called by muse, mutect2, varscan2
- KRT1 | c.552C>T p.I184= | Silent (SNP) | VAF 56/263 reads (21%) | called by muse, mutect2, varscan2
- KRT12 | c.267G>A p.L89= | Silent (SNP) | VAF 151/594 reads (25%) | catalogued as rs1164680636; called by muse, mutect2, varscan2
- KRT222 | c.90G>A p.R30= | Silent (SNP) | VAF 48/226 reads (21%) | called by muse, mutect2, varscan2
- KRT6B | c.924G>A p.Q308= | Silent (SNP) | VAF 74/277 reads (27%) | called by muse, mutect2, varscan2
- KRT9 | c.1206G>A p.K402= | Silent (SNP) | VAF 50/233 reads (21%) | catalogued as COSV55853580; called by muse, mutect2, varscan2
- LAMA2 | c.2088C>T p.A696= | Silent (SNP) | VAF 32/252 reads (13%) | catalogued as rs765615918, COSV101370006; called by muse, mutect2, varscan2
- LAMB4 | c.1203G>A p.G401= | Silent (SNP) | VAF 74/446 reads (17%) | called by muse, mutect2, varscan2
- LCT | c.3639C>T p.I1213= | Silent (SNP) | VAF 94/360 reads (26%) | catalogued as rs940172090, COSV51545793; called by muse, mutect2, varscan2
- LELP1 | c.84G>A p.E28= | Silent (SNP) | VAF 114/460 reads (25%) | called by muse, mutect2, varscan2
- LMTK3 | c.3345C>T p.A1115= | Silent (SNP) | VAF 139/543 reads (26%) | called by muse, mutect2, varscan2
- LRRC4B | c.1671C>T p.I557= | Silent (SNP) | VAF 122/480 reads (25%) | called by muse, mutect2, varscan2
- MAGEC1 | c.3207C>T p.F1069= | Silent (SNP) | VAF 119/253 reads (47%) | catalogued as rs866441854, COSV53567941; called by muse, mutect2, varscan2
- MBOAT4 | c.528G>A p.L176= | Silent (SNP) | VAF 105/377 reads (28%) | called by muse, mutect2, varscan2
- MC3R | c.150C>T p.I50= | Silent (SNP) | VAF 91/303 reads (30%) | catalogued as COSV54765022; called by muse, mutect2, varscan2
- MDN1 | c.10485G>A p.R3495= | Silent (SNP) | VAF 117/308 reads (38%) | called by muse, mutect2, varscan2
- MEIOB | c.726G>A p.R242= | Silent (SNP) | VAF 62/199 reads (31%) | catalogued as rs777310422; called by muse, mutect2, varscan2
- MIER2 | c.6G>A p.A2= | Silent (SNP) | VAF 46/303 reads (15%) | called by muse, mutect2, varscan2
- MME | c.1440C>T p.I480= | Silent (SNP) | VAF 21/142 reads (15%) | catalogued as rs777374821, COSV64708524; called by muse, mutect2, varscan2
- MMP25 | c.273C>T p.S91= | Silent (SNP) | VAF 111/381 reads (29%) | catalogued as rs1208862938; called by muse, mutect2, varscan2
- MNDA | c.885C>T p.V295= | Silent (SNP) | VAF 90/352 reads (26%) | catalogued as COSV100933395; called by muse, mutect2, varscan2
- MRGBP | c.321T>C p.L107= | Silent (SNP) | VAF 94/290 reads (32%) | called by muse, mutect2, varscan2
- MROH7 | c.3802C>T p.L1268= | Silent (SNP) | VAF 114/412 reads (28%) | called by muse, mutect2, varscan2
- MUC16 | c.17052G>A p.T5684= | Silent (SNP) | VAF 49/411 reads (12%) | catalogued as rs777439237, COSV67482576; called by muse, mutect2, varscan2
- MUC17 | c.11298G>A p.T3766= | Silent (SNP) | VAF 155/656 reads (24%) | catalogued as rs770048436, COSV100072741; called by muse, mutect2, varscan2
- MYH4 | c.4716G>A p.V1572= | Silent (SNP) | VAF 52/294 reads (18%) | called by muse, mutect2, varscan2
- MYO15A | c.222G>A p.R74= | Silent (SNP) | VAF 99/403 reads (25%) | called by muse, mutect2, varscan2
- MYO15A | c.4611G>A p.E1537= | Silent (SNP) | VAF 78/265 reads (29%) | catalogued as COSV52756062; called by muse, mutect2, varscan2
- MYO5B | c.1878G>A p.K626= | Silent (SNP) | VAF 97/340 reads (29%) | called by muse, mutect2, varscan2
- MYPOP | c.786C>T p.F262= | Silent (SNP) | VAF 103/384 reads (27%) | catalogued as rs1203659185; called by muse, mutect2, varscan2
- NCKAP5 | c.3672C>T p.P1224= | Silent (SNP) | VAF 106/388 reads (27%) | catalogued as COSV100494867; called by muse, mutect2, varscan2
- NCOA3 | c.186C>T p.F62= | Silent (SNP) | VAF 67/321 reads (21%) | called by muse, mutect2, varscan2
- NDST4 | c.1602G>T p.V534= | Silent (SNP) | VAF 73/379 reads (19%) | called by muse, mutect2, varscan2
- NIBAN2 | c.27G>A p.L9= | Silent (SNP) | VAF 87/267 reads (33%) | called by muse, mutect2, varscan2
- NLRP4 | c.270G>A p.R90= | Silent (SNP) | VAF 43/177 reads (24%) | called by muse, mutect2, varscan2
- NLRP5 | c.3303G>A p.L1101= | Silent (SNP) | VAF 68/328 reads (21%) | called by muse, mutect2
- NOS1 | c.3003G>A p.R1001= | Silent (SNP) | VAF 89/329 reads (27%) | called by muse, varscan2
- NPY4R | c.105G>A p.Q35= | Silent (SNP) | VAF 56/431 reads (13%) | called by muse, mutect2, varscan2
- NRXN3 | c.2418C>T p.T806= (on ENST00000335750 / NM_001330195.2; = p.T433= on NM_004796.6) | Silent (SNP) | VAF 95/287 reads (33%) | called by muse, mutect2, varscan2
- NUMBL | c.1728C>T p.P576= | Silent (SNP) | VAF 138/467 reads (30%) | called by muse, mutect2, varscan2
- NUP188 | c.4287G>A p.R1429= | Silent (SNP) | VAF 70/205 reads (34%) | called by muse, mutect2, varscan2
- OPRK1 | c.534C>T p.I178= | Silent (SNP) | VAF 92/367 reads (25%) | called by muse, mutect2, varscan2
- OR1J4 | c.879G>A p.R293= | Silent (SNP) | VAF 103/278 reads (37%) | catalogued as COSV61589852; called by muse, mutect2, varscan2
- OR2AG2 | c.711C>T p.A237= | Silent (SNP) | VAF 139/386 reads (36%) | called by muse, mutect2, varscan2
- OR4C12 | c.9G>A p.K3= | Silent (SNP) | VAF 38/122 reads (31%) | catalogued as COSV58860183; called by muse, mutect2, varscan2
- OR4K5 | c.171C>T p.S57= | Silent (SNP) | VAF 88/332 reads (27%) | catalogued as COSV100262458; called by muse, mutect2, varscan2
- OR4S1 | c.876G>A p.V292= | Silent (SNP) | VAF 104/293 reads (35%) | catalogued as COSV60678744; called by muse, mutect2, varscan2
- OR51A7 | c.387C>T p.P129= | Silent (SNP) | VAF 98/321 reads (31%) | catalogued as rs1408722107; called by muse, mutect2, varscan2
- OR5A2 | c.346C>T p.L116= | Silent (SNP) | VAF 140/370 reads (38%) | catalogued as rs985820307; called by muse, mutect2, varscan2
- OR5H1 | c.192G>A p.G64= | Silent (SNP) | VAF 58/334 reads (17%) | catalogued as COSV100641762; called by muse, mutect2, varscan2
- OR5H15 | c.79C>T p.L27= | Silent (SNP) | VAF 69/379 reads (18%) | catalogued as rs749354092, COSV62947489; called by muse, mutect2, varscan2
- OR6F1 | c.204C>T p.F68= | Silent (SNP) | VAF 112/407 reads (28%) | called by muse, mutect2, varscan2
- OR8B12 | c.798C>T p.P266= | Silent (SNP) | VAF 104/280 reads (37%) | catalogued as COSV60912342; called by muse, mutect2, varscan2
- OR8B4 | c.375C>T p.I125= | Silent (SNP) | VAF 110/302 reads (36%) | catalogued as COSV62070694; called by muse, mutect2
- P3H3 | c.1515C>T p.T505= | Silent (SNP) | VAF 92/416 reads (22%) | called by muse, mutect2
- PAPPA | c.2652G>A p.L884= | Silent (SNP) | VAF 98/285 reads (34%) | called by muse, mutect2, varscan2
- PCDHB16 | c.1680C>T p.F560= | Silent (SNP) | VAF 33/260 reads (13%) | catalogued as rs17853530; called by muse, varscan2
- PCLO | c.13635G>A p.Q4545= | Silent (SNP) | VAF 187/438 reads (43%) | called by muse, mutect2, varscan2
- PCSK6 | c.1825C>T p.L609= | Silent (SNP) | VAF 54/328 reads (16%) | called by muse, mutect2, varscan2
- PGK2 | c.807C>T p.I269= | Silent (SNP) | VAF 65/399 reads (16%) | catalogued as rs1244640529; called by muse, mutect2, varscan2
- PHC1 | c.783C>T p.S261= | Silent (SNP) | VAF 37/241 reads (15%) | called by muse, mutect2, varscan2
- PI4KA | c.2421C>T p.F807= | Silent (SNP) | VAF 75/293 reads (26%) | catalogued as rs563441336; called by muse, mutect2, varscan2
- PMEL | c.1368C>T p.P456= | Silent (SNP) | VAF 62/282 reads (22%) | catalogued as rs913364588; called by muse, mutect2, varscan2
- POLG | c.1446C>T p.D482= | Silent (SNP) | VAF 75/342 reads (22%) | catalogued as rs202053662; ClinVar: likely benign; called by muse, mutect2, varscan2
- POM121L12 | c.810G>A p.A270= | Silent (SNP) | VAF 146/536 reads (27%) | catalogued as rs1217595031, COSV68692325; called by muse, mutect2, varscan2
- PPP1R17 | c.193A>C p.R65= | Silent (SNP) | VAF 156/471 reads (33%) | called by muse, mutect2, varscan2
- PRAMEF12 | c.1083G>A p.V361= | Silent (SNP) | VAF 143/520 reads (28%) | catalogued as rs1334386069; called by muse, mutect2, varscan2
- PRMT8 | c.372C>T p.I124= | Silent (SNP) | VAF 101/395 reads (26%) | catalogued as COSV54214326; called by muse, mutect2, varscan2
- PROM2 | c.489C>T p.L163= | Silent (SNP) | VAF 43/365 reads (12%) | called by muse, mutect2
- PRSS55 | c.1017C>T p.L339= | Silent (SNP) | VAF 50/313 reads (16%) | catalogued as rs1297394535; called by muse, mutect2, varscan2
- PTPRB | c.3186G>A p.K1062= | Silent (SNP) | VAF 135/533 reads (25%) | catalogued as COSV54258761; called by muse, mutect2, varscan2
- PTPRT | c.3957C>T p.I1319= | Silent (SNP) | VAF 70/240 reads (29%) | called by muse, mutect2, varscan2
- PTPRT | c.3816G>A p.V1272= | Silent (SNP) | VAF 81/316 reads (26%) | called by muse, mutect2, varscan2
- PXDNL | c.2841G>A p.Q947= | Silent (SNP) | VAF 101/380 reads (27%) | catalogued as rs201891697; called by muse, mutect2, varscan2
- RABEP2 | c.465C>T p.I155= | Silent (SNP) | VAF 56/244 reads (23%) | catalogued as rs774443194, COSV62869584; called by muse, mutect2, varscan2
- RASAL1 | c.963C>T p.R321= | Silent (SNP) | VAF 100/339 reads (29%) | called by muse, mutect2, varscan2
- RELN | c.8541C>T p.I2847= | Silent (SNP) | VAF 110/492 reads (22%) | catalogued as rs746020620, COSV58997840; called by muse, mutect2, varscan2
- REXO1 | c.198C>T p.P66= | Silent (SNP) | VAF 103/350 reads (29%) | called by muse, mutect2, varscan2
- RNF123 | c.426C>T p.S142= | Silent (SNP) | VAF 48/228 reads (21%) | called by muse, mutect2, varscan2
- RP1 | c.3894C>T p.F1298= | Silent (SNP) | VAF 116/345 reads (34%) | catalogued as COSV55115168; called by muse, mutect2, varscan2
- SAMD12 | c.549G>A p.E183= | Silent (SNP) | VAF 84/283 reads (30%) | catalogued as COSV100125703; called by muse, mutect2, varscan2
- SBF1 | c.4401C>T p.P1467= | Silent (SNP) | VAF 100/357 reads (28%) | catalogued as rs11540935; called by muse, mutect2, varscan2
- SCN3A | c.2037G>A p.T679= | Silent (SNP) | VAF 31/182 reads (17%) | catalogued as rs777151004; called by muse, mutect2, varscan2
- SCO2 | c.135G>A p.E45= | Silent (SNP) | VAF 117/473 reads (25%) | catalogued as rs1180981889, COSV52690274; called by muse, mutect2, varscan2
- SERPINA11 | c.696C>T p.F232= | Silent (SNP) | VAF 90/332 reads (27%) | catalogued as COSV58242311; called by muse, mutect2, varscan2
- SHC3 | c.990G>A p.T330= | Silent (SNP) | VAF 75/215 reads (35%) | catalogued as rs749185856; called by muse, mutect2, varscan2
- SHISA6 | c.756C>T p.S252= | Silent (SNP) | VAF 58/308 reads (19%) | called by muse, mutect2, varscan2
- SIRPB2 | c.462C>T p.D154= | Silent (SNP) | VAF 73/292 reads (25%) | called by muse, mutect2, varscan2
- SLC22A25 | c.69C>T p.F23= | Silent (SNP) | VAF 61/202 reads (30%) | catalogued as COSV60600062; called by muse, mutect2, varscan2
- SLC38A8 | c.1086G>A p.A362= | Silent (SNP) | VAF 91/490 reads (19%) | catalogued as rs373825801; called by muse, mutect2, varscan2
- SLC4A1 | c.2592C>T p.I864= | Silent (SNP) | VAF 96/348 reads (28%) | catalogued as rs749334811; called by muse, mutect2, varscan2
- SLC52A2 | c.1257C>T p.G419= | Silent (SNP) | VAF 63/379 reads (17%) | catalogued as rs199767089; called by muse, mutect2, varscan2
- SLC6A13 | c.576G>A p.L192= | Silent (SNP) | VAF 88/345 reads (26%) | catalogued as rs1387073311; called by muse, mutect2, varscan2
- SPEM3 | c.1599C>T p.F533= | Silent (SNP) | VAF 83/292 reads (28%) | called by muse, mutect2, varscan2
- SPNS2 | c.561C>T p.F187= | Silent (SNP) | VAF 54/223 reads (24%) | catalogued as rs1036289624; called by muse, mutect2, varscan2
- SPPL2C | c.1131C>T p.S377= | Silent (SNP) | VAF 143/525 reads (27%) | called by muse, mutect2, varscan2
- SRCAP | c.6780C>T p.A2260= | Silent (SNP) | VAF 93/330 reads (28%) | called by muse, mutect2, varscan2
- SUFU | c.1131C>T p.S377= | Silent (SNP) | VAF 33/212 reads (16%) | catalogued as rs775396007; ClinVar: likely benign; called by muse, mutect2, varscan2
- SVOPL | c.45G>A p.R15= | Silent (SNP) | VAF 118/608 reads (19%) | called by muse, mutect2, varscan2
- TAS2R41 | c.399C>T p.L133= | Silent (SNP) | VAF 91/592 reads (15%) | catalogued as rs751812332; called by muse, mutect2, varscan2
- TDRD9 | c.495C>T p.L165= | Silent (SNP) | VAF 100/306 reads (33%) | called by muse, mutect2, varscan2
- TGM6 | c.402C>T p.L134= | Silent (SNP) | VAF 83/329 reads (25%) | called by muse, mutect2, varscan2
- TMCO3 | c.1791C>T p.V597= | Silent (SNP) | VAF 71/204 reads (35%) | called by muse, mutect2, varscan2
- TNFAIP8L3 | c.66G>A p.G22= | Silent (SNP) | VAF 99/340 reads (29%) | catalogued as COSV100552711; called by muse, varscan2
- TNS3 | c.3321G>C p.G1107= | Silent (SNP) | VAF 163/793 reads (21%) | catalogued as rs1219894658; called by muse, mutect2, varscan2
- TRAV16 | c.201G>A p.L67= | Silent (SNP) | VAF 97/287 reads (34%) | called by muse, mutect2, varscan2
- TSGA10IP | c.504C>T p.N168= | Silent (SNP) | VAF 89/278 reads (32%) | called by muse, mutect2, varscan2
- TSGA10IP | c.505C>T p.L169= | Silent (SNP) | VAF 89/283 reads (31%) | called by muse, mutect2, varscan2
- TTN | c.45606C>T p.I15202= (on ENST00000591111; = p.I7778= on NM_003319.4) | Silent (SNP) | VAF 107/363 reads (29%) | called by muse, mutect2, varscan2
- TTN | c.23619C>T p.L7873= (on ENST00000591111; = p.L6946= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 103/314 reads (33%) | catalogued as rs752689161; called by muse, mutect2, varscan2
- TTN | c.15468C>T p.F5156= (on ENST00000591111; = p.F4229= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/365 reads (17%) | catalogued as COSV100605844; called by muse, mutect2, varscan2
- UGT1A9 | c.633C>T p.I211= | Silent (SNP) | VAF 89/336 reads (26%) | called by muse, mutect2, varscan2
- USP28 | c.2229G>A p.K743= | Silent (SNP) | VAF 90/264 reads (34%) | called by muse, mutect2, varscan2
- VEGFC | c.717G>A p.A239= | Silent (SNP) | VAF 77/293 reads (26%) | catalogued as rs1324534098, COSV54606818; called by muse, mutect2, varscan2
- VWF | c.5031C>T p.I1677= | Silent (SNP) | VAF 40/347 reads (12%) | catalogued as rs755292966; called by muse, mutect2
- WDFY4 | c.5010G>A p.V1670= | Silent (SNP) | VAF 42/254 reads (17%) | catalogued as rs757891402; called by muse, mutect2, varscan2
- WDFY4 | c.6789C>T p.I2263= | Silent (SNP) | VAF 55/320 reads (17%) | called by muse, mutect2, varscan2
- WIZ | c.5481C>T p.F1827= (on ENST00000673675 / NM_001371589.1; = p.F732= on NM_021241.3) | Silent (SNP) | VAF 97/326 reads (30%) | catalogued as rs747864855, COSV54607165; called by muse, mutect2, varscan2
- WNT2 | c.585G>A p.R195= | Silent (SNP) | VAF 113/538 reads (21%) | called by muse, mutect2, varscan2
- ZAN | c.2955C>T p.I985= | Silent (SNP) | VAF 229/951 reads (24%) | called by muse, mutect2, varscan2
- ZFAT | c.3594C>T p.S1198= | Silent (SNP) | VAF 74/433 reads (17%) | catalogued as rs775214563; called by muse, mutect2, varscan2
- ZFHX3 | c.5598C>T p.A1866= | Silent (SNP) | VAF 58/329 reads (18%) | called by muse, mutect2, varscan2
- AANAT | chr17:76466194 G>A | 5'Flank (SNP) | VAF 87/290 reads (30%) | called by muse, mutect2, varscan2
- AC068790.9 | n.2560G>A | RNA (SNP) | VAF 84/333 reads (25%) | catalogued as rs1161571450; called by muse, mutect2, varscan2
- AC092718.9 | n.19G>A | RNA (SNP) | VAF 49/313 reads (16%) | called by muse, mutect2
- AC116903.1 | n.417+174G>A | Intron (SNP) | VAF 139/428 reads (32%) | catalogued as rs865947375; called by muse, mutect2, varscan2
- ADAM7 | c.579+27C>T | Intron (SNP) | VAF 62/257 reads (24%) | catalogued as COSV99444271; called by muse, mutect2, varscan2
- ANXA13 | c.15+1531C>G | Intron (SNP) | VAF 102/340 reads (30%) | called by muse, mutect2, varscan2
- ANXA8 | c.-26G>A | 5'UTR (SNP) | VAF 49/225 reads (22%) | catalogued as rs3006276; called by muse, mutect2, varscan2
- C1orf226 | chr1:162379018 C>T | 5'Flank (SNP) | VAF 63/294 reads (21%) | called by muse, mutect2, varscan2
- C4orf50 | chr4:5990110 C>T | 5'Flank (SNP) | VAF 56/252 reads (22%) | catalogued as rs1163203117; called by muse, mutect2, varscan2
- CCT2 | c.*109C>T | 3'UTR (SNP) | VAF 73/346 reads (21%) | called by muse, mutect2, varscan2
- CD300LG | c.885+378G>A | Intron (SNP) | VAF 55/263 reads (21%) | called by muse, mutect2, varscan2
- CD99 | c.475+943C>T | Intron (SNP) | VAF 104/269 reads (39%) | catalogued as rs1246311127; called by muse, mutect2, varscan2
- DUOXA1 | chr15:45117690 C>T | 3'Flank (SNP) | VAF 76/397 reads (19%) | called by muse, mutect2, varscan2
- FGFR3 | c.*1455G>A | 3'UTR (SNP) | VAF 107/391 reads (27%) | called by muse, mutect2, varscan2
- IGHE | chr14:105597723 C>T | 3'Flank (SNP) | VAF 21/123 reads (17%) | catalogued as rs1338887126; called by muse, mutect2, varscan2
- IQSEC1 | c.2847+1366G>A | Intron (SNP) | VAF 47/310 reads (15%) | called by muse, mutect2, varscan2
- MARCHF1 | c.163-34C>T | Intron (SNP) | VAF 104/365 reads (28%) | called by muse, mutect2, varscan2
- NPIPA5 | chr16:15380959 G>A | 5'Flank (SNP) | VAF 22/268 reads (8%) | called by muse, varscan2
- PTPN5 | c.1330-133G>A | Intron (SNP) | VAF 89/215 reads (41%) | called by muse, mutect2, varscan2
- RAB42 | c.-107+131C>T | Intron (SNP) | VAF 73/292 reads (25%) | catalogued as rs911151789; called by muse, mutect2, varscan2
- RYBP | c.*224C>T | 3'UTR (SNP) | VAF 18/108 reads (17%) | called by muse, mutect2, varscan2
- SH2D6 | n.223C>T | RNA (SNP) | VAF 34/102 reads (33%) | called by muse, mutect2, varscan2
- SPATA13 | c.-222-25062G>A | Intron (SNP) | VAF 61/318 reads (19%) | catalogued as rs371265729; called by muse, mutect2, varscan2
- TCTN1 | c.624+88T>C | Intron (SNP) | VAF 70/311 reads (23%) | catalogued as COSV100886024; called by muse, mutect2, varscan2
- TTN | c.34265-4238G>A | Intron (SNP) | VAF 70/300 reads (23%) | called by muse, mutect2, varscan2
- Z96074.1 | n.151+3039C>T | Intron (SNP) | VAF 73/147 reads (50%) | called by muse, mutect2, varscan2
- ZNF665 | c.-53-9189C>T | Intron (SNP) | VAF 47/217 reads (22%) | catalogued as COSV67213475, COSV67216594, COSV67218127; called by muse, mutect2, varscan2
